Somatic mutation profile of cancer-model specimen HCM-SANG-0288-C18-85A (3D Organoid; aliquot HCM-SANG-0288-C18-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-SANG-0288-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0288-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d623cb-129a-4d10-a644-7b329a434bf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0288-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0288-C18-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9a839f9-fca2-42cc-958e-4e4aae677bb2

The open-access MAF lists 3,908 somatic variants for this specimen: 2,881 protein-altering or splice-affecting, 900 silent, 127 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,122, Silent 900, Frame Shift Del 511, Frame Shift Ins 111, Nonsense Mutation 85, Intron 68, Splice Site 19, 3'UTR 19, Splice Region 18, 5'UTR 15, In Frame Del 11, 5'Flank 9.

Variants (750 of 3,908; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 111/211 reads (53%) | catalogued as rs779422412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 97/225 reads (43%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- BBS5 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 70/163 reads (43%) | catalogued as rs767221160; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 155/237 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 76/182 reads (42%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 110/241 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- CTLA4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 331/482 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553657387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.2393T>G p.L798R | Missense Mutation (SNP) | VAF 117/413 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- FGF12 | c.341G>A p.R114H (on ENST00000454309 / NM_021032.5; = p.R52H on NM_004113.6) | Missense Mutation (SNP) | VAF 112/217 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs886039903, CM166790, COSV53173851; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 69/160 reads (43%) | catalogued as rs72555359, CM910188, COSV56568786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1201dup p.R401Pfs*62 | Frame Shift Ins (INS) | VAF 126/297 reads (42%) | catalogued as rs397508082; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 52/112 reads (46%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- NDUFV1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs757486575, CM138572, COSV100295209; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTOG | c.6591G>A p.W2197* | Nonsense Mutation (SNP) | VAF 19/299 reads (6%) | catalogued as rs1193023501; ClinVar: likely pathogenic; called by muse, mutect2
- PROC | c.400+1G>A p.X134_splice | Splice Site (SNP) | VAF 151/414 reads (36%) | catalogued as rs1189377845, CS004399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RARS2 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759331139, CM123651, COSV65760478; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPSA | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs397514761, CM135109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 76/244 reads (31%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4556C>T p.P1519L (on ENST00000303395 / NM_001202435.3; = p.P1508L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372425457, COSV57661956; ClinVar: likely benign / uncertain significance / likely pathogenic / benign; called by muse, mutect2, varscan2
- SMAD3 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 132/247 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs387906854, CM116904, COSV59280826; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 97/237 reads (41%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- UMOD | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 238/493 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567310155, CM034985, CM043930, CM118890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs768179739, COSV52933345; called by muse, mutect2
- AAMP | c.44dup p.L16Tfs*9 | Frame Shift Ins (INS) | VAF 270/418 reads (65%) | catalogued as rs751284215; called by mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 70/142 reads (49%) | catalogued as rs771808127, COSV55113098; called by mutect2, varscan2
- ABCA1 | c.3808C>T p.R1270* | Nonsense Mutation (SNP) | VAF 91/205 reads (44%) | catalogued as rs575627531, CM095220, COSV66072346; called by muse, mutect2, varscan2
- ABCA10 | c.4250C>T p.T1417M | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs185824716, COSV99288804; called by muse, mutect2, varscan2
- ABCA13 | c.7735del p.I2579* | Frame Shift Del (DEL) | VAF 142/210 reads (68%) | catalogued as COSV71288654; called by mutect2, varscan2
- ABCA8 | c.4069G>A p.A1357T | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs937740354; called by muse, mutect2, varscan2
- ABCB10 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs143346649; called by muse, mutect2, varscan2
- ABCB5 | c.2957C>T p.A986V (on ENST00000404938 / NM_001163941.2; = p.A541V on NM_178559.6) | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs201974989; called by muse, mutect2
- ABCB5 | c.3361C>T p.P1121S (on ENST00000404938 / NM_001163941.2; = p.P676S on NM_178559.6) | Missense Mutation (SNP) | VAF 141/418 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1488086698; called by muse, mutect2, varscan2
- ABCC1 | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 139/335 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60682969; called by muse, mutect2, varscan2
- ABCF3 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 148/283 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53051432; called by muse, mutect2, varscan2
- ABCG1 | c.1076del p.G359Vfs*5 | Frame Shift Del (DEL) | VAF 97/254 reads (38%) | catalogued as rs1569239566, CM138401; called by mutect2, pindel, varscan2
- ABCG8 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs200433692; called by muse, mutect2, varscan2
- ABL2 | c.1168G>A p.A390T (on ENST00000502732 / NM_007314.4; = p.A375T on NM_005158.5) | Missense Mutation (SNP) | VAF 144/280 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61013110; called by muse, mutect2, varscan2
- AC015802.6 | c.141del p.S48Pfs*18 | Frame Shift Del (DEL) | VAF 62/150 reads (41%) | catalogued as rs1229993128; called by mutect2, pindel
- ACRBP | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1168368064; called by muse, mutect2, varscan2
- ACTBL2 | c.85del p.R29Gfs*7 | Frame Shift Del (DEL) | VAF 152/289 reads (53%) | catalogued as COSV101379250; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 168/174 reads (97%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 246/804 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.372); catalogued as rs531866972, COSV51895390; called by muse, varscan2
- ADAM11 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs149116155; called by muse, mutect2, varscan2
- ADAM22 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55991989; called by muse, mutect2, varscan2
- ADAM23 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 153/350 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1393967606; called by muse, mutect2, varscan2
- ADAM28 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 121/221 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56097980; called by muse, mutect2, varscan2
- ADAMTS7 | c.2590del p.L864Wfs*93 | Frame Shift Del (DEL) | VAF 173/367 reads (47%) | catalogued as rs1309405734, COSV66307015; called by mutect2, pindel, varscan2
- ADAMTSL1 | c.1910_1913del p.K637Rfs*12 | Frame Shift Del (DEL) | VAF 70/201 reads (35%) | catalogued as rs1295471077; called by pindel, varscan2
- ADAMTSL1 | c.5155C>T p.R1719C | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs746731054, COSV65883728, COSV65885375; called by muse, mutect2, varscan2
- ADCY3 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752477523; called by muse, mutect2, varscan2
- ADCY5 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV59202227; called by muse, mutect2, varscan2
- ADCY7 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 39/413 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as rs767322662; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58444937; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 116/149 reads (78%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGB | c.4522C>T p.R1508W | Missense Mutation (SNP) | VAF 116/207 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs188106474, COSV58846840; called by muse, mutect2, varscan2
- ADGRA2 | c.3926del p.G1309Afs*8 | Frame Shift Del (DEL) | VAF 155/481 reads (32%) | catalogued as rs35052362; called by mutect2, pindel, varscan2
- ADGRB1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 252/526 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1375431903; called by muse, mutect2, varscan2
- ADGRB3 | c.2308T>G p.L770V | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs755820853, COSV65408728; called by muse, mutect2, varscan2
- ADGRL2 | c.2925C>A p.S975R (on ENST00000370717 / NM_001366005.1; = p.S962R on NM_012302.4) | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54680072; called by muse, mutect2, varscan2
- ADGRL3 | c.3174G>A p.M1058I (on ENST00000506720 / NM_001322402.2; = p.M990I on NM_015236.6) | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV72229425; called by muse, mutect2, varscan2
- ADPRHL1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 169/350 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181386121, COSV62910027; called by muse, mutect2, varscan2
- AEN | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs146671175; called by muse, mutect2, varscan2
- AFDN | c.509del p.K170Rfs*53 | Frame Shift Del (DEL) | VAF 25/209 reads (12%) | catalogued as rs1431558072; called by mutect2, pindel, varscan2
- AGER | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 17/409 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV66718740; called by muse, mutect2
- AGO3 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs761675753, COSV99869178; called by muse, mutect2
- AGRN | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 213/440 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs763566707, COSV65071972; called by muse, mutect2, varscan2
- AGXT | c.471G>C p.E157D | Missense Mutation (SNP) | VAF 57/631 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV56753068; called by muse, mutect2
- AHCTF1 | c.6505dup p.I2169Nfs*35 (on ENST00000366508; = p.I2143Nfs*35 on NM_015446.5) | Frame Shift Ins (INS) | VAF 38/92 reads (41%) | catalogued as rs1251286748; called by mutect2, varscan2
- AHDC1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 190/390 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs138355578; ClinVar: benign; called by muse, varscan2
- AICDA | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs200228627; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 180/185 reads (97%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.2567dup p.N856Kfs*3 | Frame Shift Ins (INS) | VAF 58/201 reads (29%) | catalogued as rs1247973585; called by mutect2, varscan2
- ALG8 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs1272806056; called by muse, mutect2, varscan2
- ALPI | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 205/579 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758104990, COSV55015130; called by muse, mutect2, varscan2
- AMACR | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV56873422; called by muse, mutect2, varscan2
- AMBRA1 | c.3784A>G p.S1262G (on ENST00000458649 / NM_001367468.1; = p.S1172G on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 182/373 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV100093000; called by muse, mutect2, varscan2
- AMPD3 | c.829C>T p.R277* (on ENST00000396553 / NM_001025389.2; = p.R286* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as rs553182811; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 95/210 reads (45%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPTL6 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs780477052, COSV53462159; called by muse, mutect2, varscan2
- ANK2 | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148287474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.7516C>T p.R2506W | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs535569173, COSV52154500; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 87/191 reads (46%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKAR | c.3751T>C p.F1251L | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.033); catalogued as COSV55613346; called by muse, mutect2, varscan2
- ANKK1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 211/363 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1343153596; called by muse, mutect2, varscan2
- ANKRD11 | c.5315C>T p.S1772L | Missense Mutation (SNP) | VAF 56/532 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs776119333; ClinVar: uncertain significance; called by muse, mutect2
- ANKRD11 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 112/466 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773132293, COSV99970420; called by muse, mutect2, varscan2
- ANKRD13B | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs770662738, COSV61470133; called by muse, mutect2, varscan2
- ANKRD18B | c.1176del p.V393Wfs*11 | Frame Shift Del (DEL) | VAF 113/310 reads (36%) | catalogued as rs745540260; called by mutect2, pindel, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 76/194 reads (39%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANO4 | c.881C>T p.A294V (on ENST00000392977 / NM_001286615.2; = p.A259V on NM_178826.4) | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1258502826, COSV54590058; called by muse, mutect2, varscan2
- ANXA8 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 168/855 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1398885377; called by muse, mutect2, varscan2
- AP1G2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 107/228 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748127582, COSV55338027; called by muse, mutect2, varscan2
- AP2A1 | c.2323C>A p.R775S | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV58242828, COSV58243026; called by muse, mutect2, varscan2
- AP3B2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397996908; called by muse, mutect2, varscan2
- APBB1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54967686; called by muse, mutect2, varscan2
- APCDD1L | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs765708116; called by muse, varscan2
- APEX1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs367614890; called by muse, mutect2, varscan2
- APOF | c.705del p.P236Lfs*4 | Frame Shift Del (DEL) | VAF 172/397 reads (43%) | catalogued as COSV58477085; called by mutect2, pindel, varscan2
- APOF | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV58476019; called by muse, mutect2, varscan2
- ARFGEF1 | c.4894G>A p.D1632N | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs773060622, COSV51602227; called by muse, varscan2
- ARHGAP17 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 178/338 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs142115593; called by muse, varscan2
- ARHGAP39 | c.3161G>A p.R1054H (on ENST00000276826 / NM_001308208.2; = p.R1085H on NM_025251.2) | Missense Mutation (SNP) | VAF 159/335 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758945393, COSV52770190; called by muse, mutect2, varscan2
- ARHGEF15 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 189/407 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs760247454, COSV62726123; called by muse, mutect2, varscan2
- ARHGEF4 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100388721; called by muse, mutect2, varscan2
- ARID2 | c.2552del p.P851Hfs*4 | Frame Shift Del (DEL) | VAF 113/291 reads (39%) | catalogued as rs751704736; called by mutect2, pindel, varscan2
- ARMC5 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 126/395 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51656020; called by muse, varscan2
- ARMCX2 | c.469del p.M157Wfs*37 | Frame Shift Del (DEL) | VAF 70/258 reads (27%) | catalogued as COSV100168242; called by mutect2, pindel, varscan2
- ARVCF | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 147/298 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1416169283; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 92/218 reads (42%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASCC3 | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 102/214 reads (48%) | catalogued as COSV64973311; called by muse, varscan2
- ASH1L | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758885213, COSV64205321; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 100/325 reads (31%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ASPM | c.8780G>A p.R2927Q | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.435); catalogued as rs773437954; called by muse, mutect2, varscan2
- ASTN2 | c.3554C>T p.T1185I (on ENST00000313400 / NM_001365069.1; = p.T1134I on NM_014010.5) | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV56002724; called by muse, mutect2
- ASXL3 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 183/345 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1413907464; called by muse, varscan2
- ASXL3 | c.2373A>C p.K791N | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99036125; called by muse, varscan2
- ATF4 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1354963846; called by muse, mutect2
- ATF7IP | c.3730C>T p.R1244* | Nonsense Mutation (SNP) | VAF 137/237 reads (58%) | catalogued as COSV53769819; called by muse, mutect2, varscan2
- ATP13A3 | c.3341dup p.L1114Ffs*17 | Frame Shift Ins (INS) | VAF 38/81 reads (47%) | catalogued as rs1265328796; called by mutect2, varscan2
- ATP2C2 | c.2179dup p.Y727Lfs*59 | Frame Shift Ins (INS) | VAF 183/339 reads (54%) | catalogued as rs749417495; called by mutect2, pindel, varscan2
- ATP5PB | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1263366223; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs760669174; called by muse, mutect2, varscan2
- ATP6V1A | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56362102; called by muse, mutect2, varscan2
- ATR | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs753729778; called by muse, mutect2, varscan2
- ATRN | c.2011G>T p.G671W | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53523254; called by muse, varscan2
- ATXN1 | c.1010del p.P337Rfs*46 | Frame Shift Del (DEL) | VAF 46/355 reads (13%) | catalogued as COSV99785682; called by mutect2, pindel, varscan2
- AUH | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 131/281 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769894315, CM030784, COSV57862228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXIN2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 197/372 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1244431726, COSV100195707; called by muse, mutect2, varscan2
- B3GNT2 | c.924del p.F309Sfs*9 | Frame Shift Del (DEL) | VAF 96/289 reads (33%) | catalogued as rs1300549233; called by mutect2, pindel, varscan2
- BAHCC1 | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 195/410 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV57028174; called by muse, mutect2, varscan2
- BAHCC1 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs781864182, COSV57024645; called by muse, mutect2, varscan2
- BAHCC1 | c.6497G>A p.R2166H | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs553821391; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 170/340 reads (50%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BAIAP3 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.821); catalogued as rs772823496; called by muse, mutect2, varscan2
- BARD1 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 173/299 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377227840; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BARHL2 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100966067; called by muse, mutect2, varscan2
- BAZ2B | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765674376; called by muse, mutect2, varscan2
- BCL11A | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 122/237 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59627630; called by muse, mutect2, varscan2
- BCL11B | c.986G>A p.R329H (on ENST00000357195 / NM_001282237.2; = p.R258H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV61739099; called by muse, mutect2
- BCL6B | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 182/379 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as rs1163391125; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 132/350 reads (38%) | catalogued as rs751794665; called by mutect2, varscan2
- BCOR | c.3621del p.K1207Nfs*31 (on ENST00000378444 / NM_001123385.2; = p.K1173Nfs*31 on NM_017745.6) | Frame Shift Del (DEL) | VAF 133/183 reads (73%) | catalogued as CD0910695, COSV60699328; called by mutect2, pindel, varscan2
- BCORL1 | c.3896G>A p.R1299Q | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1317275824, COSV54409136; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 235/240 reads (98%) | catalogued as rs768244116; called by mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 74/146 reads (51%) | catalogued as rs752427670; called by mutect2, varscan2
- BGN | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV59038514; called by muse, mutect2, varscan2
- BHLHE40 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 127/366 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1219225546; called by muse, mutect2, varscan2
- BICDL2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54158457; called by muse, mutect2, varscan2
- BMP3 | c.821A>G p.D274G | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1299404844; called by muse, mutect2, varscan2
- BMPR2 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 141/475 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1227742705; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 119/418 reads (28%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOD1L1 | c.9151C>T p.R3051* | Nonsense Mutation (SNP) | VAF 74/144 reads (51%) | catalogued as rs369566334; called by muse, mutect2, varscan2
- BPIFA3 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.307); catalogued as rs781616507, COSV64925760; called by muse, mutect2, varscan2
- BPIFA3 | c.190del p.D64Tfs*3 | Frame Shift Del (DEL) | VAF 113/285 reads (40%) | catalogued as COSV100967159, COSV64926343; called by mutect2, pindel, varscan2
- BRINP1 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as COSV56294847; called by muse, mutect2, varscan2
- BRINP1 | c.1750T>C p.Y584H | Missense Mutation (SNP) | VAF 127/254 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs866804521; called by muse, mutect2, varscan2
- BRMS1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 112/257 reads (44%) | catalogued as rs778576158, COSV60820495; called by muse, mutect2, varscan2
- BSN | c.6367G>A p.D2123N | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as rs777067125; called by muse, mutect2, varscan2
- BST1 | c.618dup p.A207Cfs*4 | Frame Shift Ins (INS) | VAF 54/112 reads (48%) | catalogued as rs761650390; called by mutect2, varscan2
- BTN3A1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV50025197; called by muse, mutect2, varscan2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/166 reads (22%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C12orf40 | c.1110del p.K370Nfs*82 | Frame Shift Del (DEL) | VAF 93/222 reads (42%) | catalogued as COSV61133162; called by mutect2, pindel, varscan2
- C12orf56 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 156/438 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1243470275, COSV61484928; called by muse, varscan2
- C15orf62 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs994670634; called by muse, varscan2
- C20orf96 | c.337C>T p.R113* (on ENST00000360321 / NM_153269.3; = p.R112* on NM_080571.1) | Nonsense Mutation (SNP) | VAF 166/326 reads (51%) | catalogued as rs769778652, COSV64402994; called by muse, varscan2
- C2CD3 | c.4661T>C p.V1554A | Missense Mutation (SNP) | VAF 135/284 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs1359817418; called by muse, mutect2, varscan2
- C2orf16 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 155/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62677749; called by muse, mutect2, varscan2
- C2orf78 | c.1070dup p.N357Kfs*2 | Frame Shift Ins (INS) | VAF 97/202 reads (48%) | catalogued as rs1242308663; called by mutect2, varscan2
- C7orf50 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 16/453 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1348706752; called by muse, mutect2
- CA7 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58156838; called by muse, mutect2
- CACNA1C | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1394063736, COSV100219856; called by muse, mutect2, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 179/343 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by muse, mutect2, varscan2
- CACNA1E | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs781394397; called by muse, mutect2, varscan2
- CACNA1E | c.2281C>A p.P761T | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV62410322; called by muse, varscan2
- CACNA1H | c.2542G>T p.G848C | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032212; called by muse, mutect2, varscan2
- CACNA1I | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60801048; called by muse, mutect2
- CADPS | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV51878134; called by muse, mutect2, varscan2
- CALHM1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 181/412 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1328419907, COSV100324430; called by muse, mutect2, varscan2
- CALN1 | c.170C>T p.S57F (on ENST00000329008 / NM_001017440.3; = p.S99F on NM_031468.4) | Missense Mutation (SNP) | VAF 134/563 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100205773; called by muse, mutect2, varscan2
- CALN1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.084); catalogued as rs748601544, COSV67960401; called by muse, mutect2, varscan2
- CAPRIN2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51833997; called by muse, mutect2, varscan2
- CARS2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 144/300 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs774709224; called by muse, mutect2, varscan2
- CASKIN1 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 150/413 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs777007261; called by muse, mutect2, varscan2
- CASR | c.2386C>T p.R796C (on ENST00000490131; = p.R873C on NM_000388.4) | Missense Mutation (SNP) | VAF 181/374 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56140889; called by muse, mutect2, varscan2
- CASR | c.2638C>T p.Q880* (on ENST00000490131; = p.Q957* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 143/390 reads (37%) | catalogued as COSV99949529; called by muse, mutect2, varscan2
- CBLL2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs200886998, COSV60370095; called by muse, mutect2, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as COSV61761904; called by mutect2, pindel, varscan2
- CCDC105 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs369689058; called by muse, mutect2, varscan2
- CCDC120 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 259/261 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV64481196; called by muse, mutect2, varscan2
- CCDC148 | c.1251del p.I418* | Frame Shift Del (DEL) | VAF 85/148 reads (57%) | catalogued as rs758917400; called by mutect2, varscan2
- CCDC157 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748490536; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 22/178 reads (12%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC40 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs747816271; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 70/257 reads (27%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 66/159 reads (42%) | catalogued as rs749079180; called by mutect2, pindel, varscan2
- CCDC85C | c.690dup p.G231Rfs*54 | Frame Shift Ins (INS) | VAF 267/638 reads (42%) | catalogued as rs1566788126; called by mutect2, pindel, varscan2
- CCDC97 | c.547dup p.L183Pfs*4 | Frame Shift Ins (INS) | VAF 132/356 reads (37%) | catalogued as rs865828858; called by pindel, varscan2
- CCDC9B | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 132/294 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs777770251, COSV66874938, COSV66875705; called by muse, mutect2, varscan2
- CCER1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 265/564 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62647334; called by muse, mutect2, varscan2
- CCKBR | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 162/311 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.115); catalogued as rs769455834, COSV58099046, COSV58106205; called by muse, mutect2, varscan2
- CCN4 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 262/572 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs780293869; called by muse, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 68/144 reads (47%) | catalogued as rs781790231; called by mutect2, varscan2
- CCNH | c.872+1G>A p.X291_splice | Splice Site (SNP) | VAF 87/198 reads (44%) | catalogued as rs115449312; called by muse, mutect2, varscan2
- CCT5 | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV54725142; called by muse, mutect2, varscan2
- CD101 | c.2430A>G p.G810= | Splice Region (SNP) | VAF 39/114 reads (34%) | catalogued as rs1310522045; called by muse, mutect2, varscan2
- CD163L1 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 83/188 reads (44%) | catalogued as rs201216711, COSV100550007; called by muse, mutect2, varscan2
- CD180 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs150000308, COSV99842143; called by muse, mutect2
- CD300C | c.654G>C p.W218C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100423199, COSV58169544; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 62/168 reads (37%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC25B | c.1477C>T p.R493C (on ENST00000245960 / NM_021873.3; = p.R479C on NM_004358.4) | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55655804; called by muse, mutect2, varscan2
- CDC40 | c.1506del p.F502Lfs*6 | Frame Shift Del (DEL) | VAF 44/156 reads (28%) | catalogued as COSV57009608; called by mutect2, varscan2
- CDCP2 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1035036814; called by muse, mutect2, varscan2
- CDH2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs140836073; called by muse, varscan2
- CDH4 | c.2101T>C p.S701P | Missense Mutation (SNP) | VAF 255/529 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs1305825960; called by muse, mutect2, varscan2
- CDK20 | c.607del p.L203Ffs*104 (on ENST00000325303 / NM_001039803.3; = p.L182Ffs*104 on NM_012119.4) | Frame Shift Del (DEL) | VAF 127/270 reads (47%) | catalogued as COSV100308153; called by mutect2, pindel, varscan2
- CDK9 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 211/425 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767418586, COSV100953656; called by muse, mutect2, varscan2
- CDYL2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 251/372 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs62049900, COSV101629539; called by muse, mutect2, varscan2
- CEBPD | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs1235117737; called by muse, mutect2, varscan2
- CECR2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755579495, COSV52839720; called by muse, mutect2, varscan2
- CELF2 | c.1433A>G p.Q478R (on ENST00000416382 / NM_001025077.3; = p.Q491R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1231393424; called by muse, mutect2, varscan2
- CELSR2 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746803247, COSV54766316; called by muse, mutect2, varscan2
- CEMIP2 | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 156/301 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs543843123, COSV65487873; called by muse, varscan2
- CENPO | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs762800577, COSV53166991; called by muse, mutect2, varscan2
- CEP104 | c.2772G>T p.K924N | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV100986591; called by muse, mutect2, varscan2
- CEP290 | c.635dup p.N212Kfs*3 | Frame Shift Ins (INS) | VAF 70/150 reads (47%) | catalogued as rs769091629; called by mutect2, varscan2
- CEP41 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 131/358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782036013, COSV56218848; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 74/155 reads (48%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | catalogued as rs1274191949; called by mutect2, varscan2
- CGREF1 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs781048358; called by muse, mutect2, varscan2
- CHAD | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs367796724; called by muse, mutect2, varscan2
- CHAMP1 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 203/416 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV100778855; called by muse, mutect2, varscan2
- CHD1L | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 151/288 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV63614575; called by muse, mutect2, varscan2
- CHD7 | c.8182G>A p.A2728T | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as rs757725468; called by muse, mutect2, varscan2
- CHEK2 | c.1545G>T p.K515N (on ENST00000382580 / NM_001005735.2; = p.K472N on NM_007194.4) | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV60428110; called by muse, mutect2, varscan2
- CHRNB2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs1421654764, COSV63807815; called by muse, mutect2, varscan2
- CHRNE | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs930096641; called by muse, mutect2, varscan2
- CHST5 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 226/476 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360223448; called by muse, mutect2, varscan2
- CHTOP | c.293del p.G98Efs*10 | Frame Shift Del (DEL) | VAF 66/209 reads (32%) | catalogued as COSV100904747; called by mutect2, pindel, varscan2
- CIP2A | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1016784827, COSV55421712; called by muse, varscan2
- CLEC18B | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 164/772 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs369764401; called by muse, mutect2, varscan2
- CLHC1 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 71/147 reads (48%) | catalogued as rs1287861723; called by muse, mutect2, varscan2
- CLIP4 | c.1014del p.K339Sfs*11 | Frame Shift Del (DEL) | VAF 61/158 reads (39%) | catalogued as rs1387551205; called by mutect2, pindel, varscan2
- CLK4 | c.802T>C p.Y268H | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV104412666; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 140/148 reads (95%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 62/476 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.457); catalogued as rs770360744, COSV61611161; called by muse, varscan2
- CLPTM1L | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs140255940; called by muse, mutect2, varscan2
- CLTCL1 | c.4784C>T p.A1595V (on ENST00000427926 / NM_007098.4; = p.A1538V on NM_001835.4) | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.455); catalogued as COSV99311076; called by muse, mutect2, varscan2
- CLTCL1 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1027111957; called by muse, mutect2, varscan2
- CMYA5 | c.5338G>C p.A1780P | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1055859573; called by muse, mutect2, varscan2
- CNBD1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV101582180; called by muse, mutect2, varscan2
- CNBD2 | c.1306G>A p.D436N (on ENST00000373973 / NM_001365709.1; = p.D432N on NM_080834.4) | Missense Mutation (SNP) | VAF 196/375 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs748255965, COSV100839098; called by muse, mutect2, varscan2
- CNGA4 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs370277883, COSV99792231; called by muse, mutect2, varscan2
- CNGB3 | c.389C>G p.A130G | Missense Mutation (SNP) | VAF 146/318 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs763732485, COSV60685215; called by muse, varscan2
- CNNM1 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs143111634; called by muse, mutect2, varscan2
- CNOT3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 57/401 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.411); catalogued as COSV99651487; called by muse, mutect2, varscan2
- CNTLN | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs754809682, COSV52068083, COSV99263553; called by muse, mutect2, varscan2
- CNTN5 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679074; called by muse, mutect2
- CNTN6 | c.2178A>C p.E726D | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100612109, COSV63190764; called by muse, mutect2, varscan2
- CNTNAP5 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs775432842, COSV70482055, COSV70489649; called by muse, mutect2
- CNTNAP5 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207750958, COSV70472432, COSV70483251; called by muse, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 139/286 reads (49%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.2142A>C p.K714N | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100617967; called by muse, mutect2, varscan2
- COL11A2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 136/412 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV59497516; called by muse, mutect2, varscan2
- COL1A1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435869455, COSV56804765; called by muse, mutect2, varscan2
- COL1A1 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 127/277 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56809627; called by muse, mutect2, varscan2
- COL21A1 | c.425T>G p.L142R | Missense Mutation (SNP) | VAF 141/296 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99780502; called by muse, mutect2, varscan2
- COL23A1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779240932; called by muse, mutect2, varscan2
- COL23A1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 209/387 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1328110459; called by muse, mutect2, varscan2
- COL25A1 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 68/215 reads (32%) | catalogued as rs759316372, COSV67654943; called by muse, mutect2, varscan2
- COL3A1 | c.4372G>A p.V1458M | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs751427069; called by muse, mutect2, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 45/335 reads (13%) | catalogued as rs1277273445; called by mutect2, pindel, varscan2
- COL9A3 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 143/270 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1422176468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC12 | c.1479del p.G494Efs*152 | Frame Shift Del (DEL) | VAF 114/386 reads (30%) | catalogued as rs1370347479, COSV68371585, COSV68371960; called by mutect2, pindel, varscan2
- COPA | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV54098185; called by muse, mutect2, varscan2
- CPED1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 160/476 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779941795; called by muse, mutect2, varscan2
- CPED1 | c.2778del p.K926Nfs*6 | Frame Shift Del (DEL) | VAF 64/330 reads (19%) | catalogued as rs777945397; called by mutect2, pindel, varscan2
- CPNE7 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 220/342 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767725210, COSV52016440; called by muse, mutect2
- CPNE8 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs750050507, COSV58844155; called by muse, mutect2, varscan2
- CPS1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 41/482 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs375511261; called by muse, mutect2
- CPSF4 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 64/332 reads (19%) | catalogued as rs760248771; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 102/272 reads (38%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CRB1 | c.613A>T p.I205L | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.553); catalogued as rs1200002459, CD011132; called by muse, mutect2, varscan2
- CREB5 | c.689C>T p.S230L (on ENST00000357727 / NM_182898.4; = p.S223L on NM_004904.3) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100743764; called by muse, mutect2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 97/131 reads (74%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CROCC2 | c.3436del p.D1146Tfs*13 | Frame Shift Del (DEL) | VAF 169/600 reads (28%) | catalogued as rs1255916134; called by mutect2, pindel, varscan2
- CRYBG3 | c.7079G>T p.R2360L | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as rs373418086; called by muse, mutect2, varscan2
- CSF1 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 205/434 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100294916, COSV99052068; called by muse, mutect2, varscan2
- CSH2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 144/628 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs755600756, COSV100400231; called by muse, mutect2, varscan2
- CSMD1 | c.2672G>C p.G891A (on ENST00000520002; = p.G890A on NM_033225.6) | Missense Mutation (SNP) | VAF 161/323 reads (50%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1454337672; called by muse, mutect2, varscan2
- CSMD2 | c.8380G>A p.A2794T | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs1384869792; called by muse, varscan2
- CSPG4 | c.5290G>A p.E1764K | Missense Mutation (SNP) | VAF 200/408 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs745751249, COSV57892059; called by muse, mutect2, varscan2
- CSPP1 | c.377C>A p.S126Y (on ENST00000676605; = p.S85Y on NM_024790.6) | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99138129; called by muse, varscan2
- CSTF2T | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs774284008; called by muse, mutect2, varscan2
- CTF1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 137/245 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs886051924; called by muse, mutect2, varscan2
- CTNNA3 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138314889, COSV101047576; ClinVar: uncertain significance; called by muse, mutect2
- CTNND2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1206155713, COSV58892878; called by muse, mutect2, varscan2
- CTRL | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs756085763; called by muse, mutect2, varscan2
- CTTNBP2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 100/358 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200938049; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 82/194 reads (42%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CYP26A1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 216/443 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs200654050; called by muse, mutect2, varscan2
- CYP2A7 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1188048842, COSV99394551; called by muse, mutect2, varscan2
- CYP2J2 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 83/194 reads (43%) | catalogued as rs750655796, COSV64606648; called by muse, varscan2
- CYP4B1 | c.11G>T p.S4I | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99597307; called by muse, mutect2, varscan2
- CYRIB | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 91/206 reads (44%) | catalogued as COSV67828434, COSV67828765; called by muse, mutect2, varscan2
- CYTH4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 149/299 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs567728312, COSV50631217; called by muse, mutect2, varscan2
- DCAF13 | c.413T>C p.M138T | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1475695161; called by muse, mutect2, varscan2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 74/150 reads (49%) | catalogued as rs755674655; called by mutect2, varscan2
- DCAF8 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1205424160, COSV100470166; called by muse, mutect2, varscan2
- DCHS1 | c.7636C>T p.P2546S | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1221764382; called by muse, varscan2
- DCHS1 | c.6866C>T p.A2289V | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs571494644, COSV55030025; called by muse, mutect2, varscan2
- DCHS1 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576117138; called by muse, mutect2, varscan2
- DCLK1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 46/388 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs760301962, COSV55184477; called by muse, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 72/154 reads (47%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX20 | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs757781070; called by muse, mutect2, varscan2
- DDX47 | c.426dup p.P143Tfs*13 | Frame Shift Ins (INS) | VAF 58/123 reads (47%) | catalogued as rs769535432; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 52/118 reads (44%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND4A | c.5563C>T p.R1855* | Nonsense Mutation (SNP) | VAF 80/193 reads (41%) | catalogued as rs761943167, COSV101475363; called by muse, mutect2, varscan2
- DENND4A | c.1521A>G p.I507M | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as rs199813601; called by muse, mutect2, varscan2
- DEPDC5 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 164/349 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs372489331; ClinVar: uncertain significance; called by muse, varscan2
- DES | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs794728996, COSV64660780; called by muse, mutect2
- DEUP1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99977238; called by muse, mutect2, varscan2
- DGKD | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.084); catalogued as rs1442916579; called by muse, mutect2, varscan2
- DGKD | c.1811G>A p.R604Q (on ENST00000264057 / NM_152879.3; = p.R560Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs751388605; called by muse, mutect2, varscan2
- DHCR24 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 143/278 reads (51%) | catalogued as rs563822834, COSV64875432; called by muse, mutect2, varscan2
- DHRS12 | c.517G>A p.V173I (on ENST00000444610 / NM_001377930.1; = p.V124I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs145669707; called by muse, mutect2, varscan2
- DHRSX | c.119del p.P40Hfs*8 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as rs1374998959; called by pindel, varscan2
- DIAPH1 | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52767820; called by muse, mutect2, varscan2
- DIPK1C | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235254082, COSV59724131; called by muse, mutect2, varscan2
- DIS3L2 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 162/267 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs774732040, COSV56062854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK2 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 160/333 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.092); catalogued as COSV53393532, COSV99569176; called by muse, mutect2, varscan2
- DLGAP3 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 268/527 reads (51%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV52391825; called by muse, mutect2, varscan2
- DLL1 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs778087366; called by muse, mutect2, varscan2
- DNAH11 | c.7319C>T p.A2440V | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1028235968; called by muse, mutect2
- DNAH3 | c.4433C>T p.A1478V | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373934227; called by muse, varscan2
- DNAH5 | c.12599A>C p.K4200T | Missense Mutation (SNP) | VAF 148/300 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DNAH9 | c.6884A>C p.N2295T | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs1412808239; called by muse, mutect2, varscan2
- DNALI1 | c.625T>C p.S209P (on ENST00000296218; = p.S187P on NM_003462.5) | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV104407132; called by muse, mutect2, varscan2
- DNASE2B | c.152del p.R51Nfs*11 | Frame Shift Del (DEL) | VAF 45/124 reads (36%) | catalogued as COSV99055583; called by mutect2, pindel, varscan2
- DNHD1 | c.8518C>T p.R2840* | Nonsense Mutation (SNP) | VAF 13/286 reads (5%) | catalogued as rs1342727634, COSV54439208; called by muse, mutect2
- DNMT3A | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1347653303, COSV53044862; called by muse, mutect2, varscan2
- DOCK8 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs140779178; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 49/301 reads (16%) | catalogued as rs748134881; called by mutect2, varscan2
- DOCK9 | c.4002dup p.T1335Yfs*4 (on ENST00000376460 / NM_001366676.2; = p.T1336Yfs*4 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 44/110 reads (40%) | catalogued as rs1344550381; called by mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 130/325 reads (40%) | catalogued as rs750520568; called by mutect2, pindel, varscan2
- DPP4 | c.668del p.L223* | Frame Shift Del (DEL) | VAF 96/231 reads (42%) | catalogued as COSV100858900; called by mutect2, pindel, varscan2
- DPP6 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV66724657; called by muse, varscan2
- DPP6 | c.550dup p.I184Nfs*2 (on ENST00000377770 / NM_001364500.2; = p.I122Nfs*2 on NM_001936.5) | Frame Shift Ins (INS) | VAF 50/204 reads (25%) | catalogued as rs773847741; called by mutect2, varscan2
- DPYD | c.1840A>G p.S614G | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64605563; called by muse, mutect2, varscan2
- DTNA | c.656del p.P219Rfs*13 | Frame Shift Del (DEL) | VAF 71/164 reads (43%) | catalogued as COSV52020712; called by mutect2, pindel, varscan2
- DTX2 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 158/494 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377413711; called by muse, mutect2, varscan2
- DTX3 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 121/233 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs748571053, COSV54086776; called by muse, mutect2, varscan2
- DUS2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1400372156, COSV62708311, COSV62710088; called by muse, mutect2, varscan2
- DUSP9 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs868923152; called by muse, mutect2, varscan2
- DYNC2H1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs777540722; called by muse, varscan2
- DYNC2H1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 108/200 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV62093166; called by muse, varscan2
- E2F4 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 172/364 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.441); catalogued as rs201338753; called by muse, varscan2
- E2F7 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59743756; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 83/198 reads (42%) | catalogued as rs756314578; called by mutect2, pindel, varscan2
- EEF1D | c.393C>T p.H131= | Splice Region (SNP) | VAF 128/256 reads (50%) | catalogued as rs185553839; called by muse, mutect2, varscan2
- EFCAB7 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327777547; called by muse, varscan2
- EFNB3 | c.29del p.G10Afs*49 | Frame Shift Del (DEL) | VAF 86/214 reads (40%) | catalogued as COSV99872906; called by mutect2, pindel, varscan2
- EGFL8 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 152/345 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs371176366; called by muse, mutect2, varscan2
- EGFLAM | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 108/210 reads (51%) | catalogued as rs1220128597, COSV59295089; called by muse, mutect2, varscan2
- EHBP1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs750441921, COSV99859654; called by muse, mutect2, varscan2
- EHD2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 204/398 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs148032446; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 100/172 reads (58%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 49/117 reads (42%) | catalogued as rs1290746509; called by mutect2, pindel, varscan2
- ELAPOR1 | c.1867del p.T623Lfs*5 | Frame Shift Del (DEL) | VAF 120/321 reads (37%) | catalogued as rs1437113456; called by mutect2, pindel, varscan2
- ELK3 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866414172, COSV99957464; called by muse, mutect2, varscan2
- ELMO2 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as rs760009580, COSV51682755, COSV51686266; called by muse, mutect2, varscan2
- ELP2 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60853150; called by muse, mutect2
- ELSPBP1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 86/179 reads (48%) | catalogued as rs767248894, COSV60413404; called by muse, mutect2, varscan2
- EMILIN2 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 137/282 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145317774, COSV54421542; called by muse, mutect2, varscan2
- EN1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); catalogued as rs1273430728; called by muse, mutect2, varscan2
- ENAM | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 123/250 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV68535627; called by muse, mutect2, varscan2
- ENGASE | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1184738524; called by muse, mutect2
- ENOX2 | c.1265G>A p.R422H (on ENST00000338144 / NM_001382520.1; = p.R393H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/159 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs770825086, COSV57650755; called by muse, mutect2, varscan2
- EPHA10 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 194/391 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575993574, COSV60403035; called by muse, mutect2, varscan2
- EPHB1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.483); catalogued as rs372758942, COSV67674637; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 158/316 reads (50%) | catalogued as COSV99212515; called by muse, mutect2, varscan2
- EPN2 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 151/338 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs774601697; called by muse, mutect2, varscan2
- EPN3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374799071; called by muse, mutect2, varscan2
- ERCC3 | c.2183T>A p.V728E | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53426052; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 134/256 reads (52%) | catalogued as rs779855268; called by mutect2, varscan2
- ERVV-1 | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 48/482 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1568456821; called by muse, varscan2
- ESCO2 | c.595del p.I199* | Frame Shift Del (DEL) | VAF 91/196 reads (46%) | catalogued as rs1563468940; called by mutect2, pindel, varscan2
- ESD | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV66339914; called by muse, mutect2, varscan2
- ESRRB | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 226/465 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV55061542; called by muse, mutect2, varscan2
- ESYT2 | c.2269G>A p.A757T (on ENST00000613624; = p.A681T on NM_020728.3) | Missense Mutation (SNP) | VAF 206/571 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs773507830; called by muse, mutect2, varscan2
- ETAA1 | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV55475697; called by muse, mutect2, varscan2
- EXD3 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1395931522; called by muse, mutect2, varscan2
- EXOC3L1 | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs774545201; called by muse, mutect2, varscan2
- EYA4 | c.1703A>G p.Y568C (on ENST00000531901 / NM_001301013.1; = p.Y562C on NM_004100.5) | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199621266, COSV100766286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F2RL3 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 178/485 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs754030734; called by muse, varscan2
- FAM135B | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV52706722; called by muse, mutect2, varscan2
- FAM13B | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.643); catalogued as rs765250293; called by muse, mutect2, varscan2
- FAM13C | c.1620dup p.K541* | Frame Shift Ins (INS) | VAF 97/268 reads (36%) | catalogued as rs1211493129; called by mutect2, pindel, varscan2
- FAM166A | c.728A>G p.D243G | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs373939553; called by muse, mutect2, varscan2
- FAM170B | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 142/290 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV61254047; called by muse, mutect2, varscan2
- FAM184A | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1236042738, COSV58856982; called by muse, mutect2, varscan2
- FAM193A | c.2954C>T p.S985F | Missense Mutation (SNP) | VAF 114/315 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV61192683; called by muse, mutect2, varscan2
- FAM222A | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as rs745618000, COSV100734597; called by muse, mutect2, varscan2
- FAM50B | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs771811466, COSV66654505; called by muse, mutect2, varscan2
- FAM50B | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV66655022; called by muse, varscan2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 128/316 reads (41%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FAM83C | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV104428561; called by muse, mutect2, varscan2
- FAM83G | c.1872G>T p.E624D | Missense Mutation (SNP) | VAF 200/392 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764496911; called by muse, mutect2, varscan2
- FAM98A | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99479002; called by muse, mutect2
- FANCD2OS | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.116); catalogued as rs1211970569; called by muse, mutect2, varscan2
- FANK1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs796808583; called by muse, varscan2
- FAP | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 102/211 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs775116487, COSV51867064; called by muse, varscan2
- FAT1 | c.8965del p.R2989Gfs*20 | Frame Shift Del (DEL) | VAF 28/265 reads (11%) | catalogued as rs748652484; called by mutect2, pindel
- FAT2 | c.10718C>T p.T3573I | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs763267937; called by muse, mutect2
- FAT3 | c.2410T>C p.Y804H | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1163063931; called by muse, mutect2, varscan2
- FAT3 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.102); catalogued as COSV53120510; called by muse, mutect2, varscan2
- FAT4 | c.7442C>T p.T2481I | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs752015424; called by muse, mutect2, varscan2
- FBXO40 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 81/184 reads (44%) | catalogued as rs139292085, COSV57525467; called by muse, mutect2, varscan2
- FBXW8 | c.395A>G p.D132G (on ENST00000309909; = p.D170G on NM_012174.1) | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752339865; called by muse, mutect2, varscan2
- FGA | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV57394060; called by muse, mutect2, varscan2
- FGR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 155/302 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs750537230; called by muse, mutect2, varscan2
- FIG4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747284213, COSV57787058, COSV57787107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGN | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.963); catalogued as COSV60766717; called by muse, mutect2, varscan2
- FITM2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 153/299 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs370245406; called by muse, mutect2, varscan2
- FKBP6 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs545404821; called by muse, mutect2, varscan2
- FLG | c.6453del p.S2152Pfs*7 | Frame Shift Del (DEL) | VAF 91/319 reads (29%) | catalogued as rs767943691, COSV64238459; called by mutect2, pindel, varscan2
- FLNC | c.2747G>T p.R916L | Missense Mutation (SNP) | VAF 153/544 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs143720860; called by muse, mutect2, varscan2
- FLNC | c.5602G>T p.G1868C | Missense Mutation (SNP) | VAF 181/560 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368957; called by muse, mutect2, varscan2
- FLT1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1161996687, COSV56724342; called by muse, mutect2, varscan2
- FLT4 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs146167161, COSV56099675, COSV56115874; called by muse, mutect2, varscan2
- FMNL2 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 174/345 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs779038308; called by muse, mutect2, varscan2
- FN1 | c.4088G>A p.G1363D | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT tolerated (0.71); PolyPhen probably damaging (1); catalogued as COSV60563140; called by muse, varscan2
- FNDC5 | c.618del p.L207Ffs*69 | Frame Shift Del (DEL) | VAF 165/386 reads (43%) | catalogued as COSV65106005; called by mutect2, pindel, varscan2
- FNDC7 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765229312, COSV54757640; called by muse, mutect2, varscan2
- FNTB | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 99/282 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs142942714; called by muse, mutect2, varscan2
- FOXC1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 306/614 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1437969513; called by muse, varscan2
- FOXC2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 53/744 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100234352; called by muse, mutect2
- FOXC2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 196/866 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.104); catalogued as rs1384708266, COSV57444019; called by muse, mutect2, varscan2
- FOXF1 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 344/566 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM150913, COSV52286979; called by muse, varscan2
- FOXF1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 244/400 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1296551901; called by muse, mutect2, varscan2
- FOXJ2 | c.1106del p.P369Rfs*53 | Frame Shift Del (DEL) | VAF 194/459 reads (42%) | catalogued as COSV99368681; called by mutect2, pindel, varscan2
- FOXL1 | c.102del p.A35Rfs*4 | Frame Shift Del (DEL) | VAF 134/630 reads (21%) | catalogued as COSV57215520; called by mutect2, varscan2
- FOXL2 | c.576del p.K193Sfs*78 | Frame Shift Del (DEL) | VAF 63/490 reads (13%) | catalogued as CD025235; called by mutect2, pindel, varscan2
- FOXO1 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1482440466; called by mutect2, varscan2
- FOXP1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs935869094, COSV59516900; called by muse, varscan2
- FRMD4A | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 286/539 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1442259063; called by muse, varscan2
- FSCB | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV61218991; called by muse, varscan2
- FST | c.315del p.K105Nfs*4 | Frame Shift Del (DEL) | VAF 90/213 reads (42%) | catalogued as rs1561296831; called by mutect2, pindel, varscan2
- FSTL5 | c.366dup p.Q123Tfs*9 | Frame Shift Ins (INS) | VAF 80/189 reads (42%) | catalogued as rs1293605811; called by mutect2, pindel, varscan2
- FTCD | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 123/264 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as rs1010026593; called by muse, mutect2, varscan2
- FUT1 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 181/385 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100038113; called by muse, mutect2, varscan2
- FUT9 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs1404954233, COSV56142623; called by muse, mutect2, varscan2
- FYB2 | c.1153del p.M385* | Frame Shift Del (DEL) | VAF 59/152 reads (39%) | catalogued as rs762431846; called by mutect2, pindel, varscan2
- FZD2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 218/427 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59528798; called by muse, mutect2, varscan2
- FZD9 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 34/794 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.316); catalogued as rs782339488, COSV59988261; called by muse, mutect2
- GAD2 | c.1163A>C p.N388T | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV52170113; called by muse, mutect2, varscan2
- GALM | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1159501195; called by muse, mutect2, varscan2
- GALNT17 | c.1634A>C p.K545T | Missense Mutation (SNP) | VAF 117/381 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100357074; called by muse, mutect2, varscan2
- GALNT3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200762567; called by muse, mutect2, varscan2
- GALR2 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 183/533 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as rs759813358, COSV57163202; called by muse, mutect2, varscan2
- GAN | c.849_850del p.R283Sfs*17 | Frame Shift Del (DEL) | VAF 46/188 reads (24%) | catalogued as rs1193445741; called by pindel, varscan2
- GARRE1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 118/272 reads (43%) | catalogued as rs1412477360; called by muse, mutect2, varscan2
- GAS2L1 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1234070860; called by muse, mutect2, varscan2
- GATA6 | c.1744T>A p.S582T | Missense Mutation (SNP) | VAF 158/277 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV52525371; called by muse, mutect2, varscan2
- GCN1 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 190/383 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as COSV56107041; called by muse, mutect2, varscan2
- GDF10 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1228721990; called by muse, varscan2
- GDPD1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.69); PolyPhen benign (0.129); catalogued as rs1161499615; called by muse, mutect2, varscan2
- GFRA2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 196/395 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs922408782; called by muse, mutect2, varscan2
- GIMAP1 | c.851del p.G284Afs*39 | Frame Shift Del (DEL) | VAF 344/748 reads (46%) | catalogued as rs756722011, COSV100212336; called by pindel, varscan2
- GIMAP6 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 360/540 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs375860624, COSV61034548; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 56/128 reads (44%) | catalogued as rs750227570; called by mutect2, varscan2
- GJA8 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 106/356 reads (30%) | catalogued as COSV53789902; called by mutect2, pindel, varscan2
- GJB3 | c.136del p.D46Mfs*222 | Frame Shift Del (DEL) | VAF 147/402 reads (37%) | catalogued as COSV64904641; called by mutect2, pindel, varscan2
- GJD4 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.144); catalogued as COSV58703315; called by muse, mutect2, varscan2
- GLDN | c.1382A>G p.Q461R | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as rs147993127; called by muse, mutect2, varscan2
- GLI2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 152/350 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1021891477; called by muse, mutect2, varscan2
- GLIS3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs764764239; called by muse, mutect2, varscan2
- GLRA3 | c.1322del p.L441* | Frame Shift Del (DEL) | VAF 109/222 reads (49%) | catalogued as rs1411021425; called by mutect2, pindel, varscan2
- GLRA4 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 209/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1436992560; called by muse, mutect2, varscan2
- GNB2 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 158/432 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.375); catalogued as rs375676173; called by muse, mutect2, varscan2
- GNB5 | c.530C>T p.T177M (on ENST00000261837 / NM_016194.4; = p.T135M on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs1165379988, COSV99953196; called by muse, mutect2, varscan2
- GOLM1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748551343, COSV57415891; called by muse, mutect2
- GPATCH2 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.594); catalogued as rs1282610754; called by muse, mutect2, varscan2
- GPR137 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 194/373 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs945401079, COSV57402226; called by muse, mutect2, varscan2
- GPR155 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs769390867; called by muse, mutect2, varscan2
- GPR158 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285726905, COSV66275590; called by muse, mutect2, varscan2
- GPR158 | c.3366dup p.K1123Qfs*10 | Frame Shift Ins (INS) | VAF 136/351 reads (39%) | catalogued as rs771672605; called by mutect2, pindel, varscan2
- GPR173 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 231/235 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1556805906; called by muse, mutect2, varscan2
- GPR32 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.65); catalogued as rs942404673; called by muse, mutect2, varscan2
- GPR50 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 169/243 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1241914898; called by muse, mutect2, varscan2
- GRID1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 229/486 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs770555419, COSV60049348; called by muse, mutect2, varscan2
- GRID2IP | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765792714; called by muse, mutect2
- GRIFIN | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 216/675 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.397); catalogued as rs781700249; called by muse, mutect2, varscan2
- GRIK4 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 164/348 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs1474855748; called by muse, mutect2
- GRIN1 | c.2279T>C p.I760T | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100160812; called by muse, mutect2
- GRIN2C | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 256/543 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.139); catalogued as rs1409139750; called by muse, mutect2, varscan2
- GRM5 | c.3547C>A p.P1183T (on ENST00000305447 / NM_001143831.2; = p.P1151T on NM_000842.4) | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV59609046; called by muse, mutect2, varscan2
- GRM5 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752621407, COSV59607226, COSV59613591; called by muse, mutect2
- GSDME | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 129/449 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs377050475; called by muse, mutect2, varscan2
- GSPT1 | c.89C>T p.A30V (on ENST00000420576 / NM_001130007.2; = p.A168V on NM_002094.4) | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs760497642, COSV70452599; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs782200582; called by muse, mutect2, varscan2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2
- GTPBP4 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1178848625, COSV62550817; called by muse, mutect2, varscan2
- GUCY2D | c.571del p.Q191Rfs*25 | Frame Shift Del (DEL) | VAF 239/583 reads (41%) | catalogued as rs1555634640; called by mutect2, pindel, varscan2
- H2BC12 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.357); catalogued as rs1303259461; called by muse, mutect2, varscan2
- H3-3B | c.52dup p.R18Pfs*80 | Frame Shift Ins (INS) | VAF 70/192 reads (36%) | catalogued as rs779064600; called by pindel, varscan2
- HACE1 | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53501056; called by muse, mutect2, varscan2
- HAND1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50562583; called by muse, mutect2, varscan2
- HAVCR1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as rs889977270, COSV59401024; called by muse, mutect2, varscan2
- HDAC4 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 162/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772980393, COSV100614458; called by muse, mutect2, varscan2
- HDAC4 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 161/482 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs137972289, COSV100614136; called by muse, mutect2, varscan2
- HELT | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 257/533 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs767222911; called by muse, mutect2, varscan2
- HELZ2 | c.3557G>A p.R1186Q (on ENST00000467148 / NM_001037335.2; = p.R617Q on NM_033405.3) | Missense Mutation (SNP) | VAF 211/437 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs761892594, COSV64409102; called by muse, mutect2, varscan2
- HERC2 | c.5434G>A p.A1812T | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1487318843, COSV99877021; called by muse, mutect2, varscan2
- HHAT | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475853230; called by muse, mutect2, varscan2
- HIKESHI | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766714056; called by muse, varscan2
- HIVEP3 | c.7006C>T p.R2336C | Missense Mutation (SNP) | VAF 63/471 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs200303069; called by muse, mutect2, varscan2
- HKDC1 | c.2339T>G p.I780S | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV63578902; called by muse, mutect2, varscan2
- HLA-A | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 176/420 reads (42%) | catalogued as rs199474568, CM099029, COSV65137049; called by muse, mutect2
- HLA-F | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 146/326 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs750465081; called by muse, mutect2, varscan2
- HMGXB3 | c.4180C>T p.H1394Y (on ENST00000613459; = p.H1148Y on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1483322629; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 49/126 reads (39%) | catalogued as rs761272507; called by mutect2, varscan2
- HOXD11 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs556598533; called by muse, mutect2, varscan2
- HSD11B1L | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 162/364 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs759313781; called by muse, mutect2, varscan2
- HSP90AB1 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1171829974, COSV62336435; called by muse, mutect2, varscan2
- HSP90AB1 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV99241503; called by muse, mutect2, varscan2
- HSPA4L | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763175283; called by muse, mutect2, varscan2
- HSPG2 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 138/396 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs757543686; called by muse, mutect2, varscan2
- HTR5A | c.953T>C p.I318T | Missense Mutation (SNP) | VAF 142/568 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs748499187; called by muse, mutect2, varscan2
- HTT | c.9148G>A p.A3050T | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1486656712, COSV61863267; called by muse, varscan2
- HUWE1 | c.6484C>T p.R2162W | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53333602, COSV53361602; called by muse, mutect2, varscan2
- HYDIN | c.11431C>T p.R3811C | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs111706881, COSV66637901; called by muse, mutect2, varscan2
- HYDIN | c.2144C>A p.P715Q | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs780885009; called by muse, mutect2
- IDI2 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 127/297 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as COSV99479087; called by muse, varscan2
- IFNA10 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 141/351 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs1175661186, COSV53331684; called by muse, varscan2
- IGF2R | c.4500G>A p.W1500* | Nonsense Mutation (SNP) | VAF 121/263 reads (46%) | catalogued as COSV63630943; called by muse, mutect2, varscan2
- IGFN1 | c.3122C>T p.P1041L (on ENST00000295591 / NM_001367841.1; = p.P3498L on NM_001164586.2) | Missense Mutation (SNP) | VAF 130/239 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs375512984; called by muse, varscan2
- IGHG2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 205/623 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as rs371694856; called by muse, mutect2, varscan2
- IGHG3 | c.782del p.I262Sfs*27 | Frame Shift Del (DEL) | VAF 156/409 reads (38%) | catalogued as rs1566732304; called by mutect2, pindel, varscan2
- IGHV1-46 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 153/277 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1337425972; called by muse, mutect2, varscan2
- IGHV3-16 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs567087662; called by muse, mutect2, varscan2
- IGKV3D-7 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.338); catalogued as rs1278181973; called by muse, mutect2, varscan2
- IGLV3-1 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs751013962; called by muse, mutect2, varscan2
- IGSF10 | c.3269C>T p.P1090L | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs367677865, COSV56791807; called by muse, mutect2, varscan2
- IKZF2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 148/496 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs768257175, COSV59581913; called by muse, mutect2, varscan2
- IKZF3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 136/319 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs748075678; called by muse, mutect2, varscan2
- IL1RL2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770693121, COSV51819518; called by muse, varscan2
- IL4I1 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 223/427 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as rs974930487; called by muse, mutect2, varscan2
- INO80B | c.1057del p.L353Ffs*? | Frame Shift Del (DEL) | VAF 87/237 reads (37%) | catalogued as rs1333623296, COSV51969567; called by mutect2, pindel, varscan2
- INO80D | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 158/470 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319786184, COSV68958136; called by muse, mutect2, varscan2
- INSR | c.3991C>T p.R1331C | Missense Mutation (SNP) | VAF 186/383 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs374098153; called by muse, mutect2, varscan2
- INSRR | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 128/283 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs982208257; called by muse, mutect2, varscan2
- INSRR | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 195/425 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs551984020, COSV63877169; called by muse, mutect2, varscan2
- INTS5 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV57951528; called by muse, mutect2, varscan2
- IP6K2 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs1487341346, COSV53663728; called by mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 46/111 reads (41%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPO4 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 159/314 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs771283996; called by muse, mutect2, varscan2
- IQCA1 | c.1104dup p.Q369Tfs*10 | Frame Shift Ins (INS) | VAF 142/236 reads (60%) | catalogued as rs767039128; called by mutect2, varscan2
- IQGAP3 | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs144453505; called by muse, mutect2, varscan2
- IQSEC2 | c.1937G>A p.R646H (on ENST00000642864 / NM_001111125.3; = p.R441H on NM_015075.2) | Missense Mutation (SNP) | VAF 196/279 reads (70%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100945014; called by muse, mutect2, varscan2
- IRF2BP1 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV56195367; called by muse, mutect2, varscan2
- IRF7 | c.316A>G p.T106A (on ENST00000397566; = p.T93A on NM_001572.5) | Missense Mutation (SNP) | VAF 78/611 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs953876367; called by muse, mutect2, varscan2
- IRX2 | c.810C>G p.D270E | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183565355; called by muse, mutect2, varscan2
- ISLR2 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 238/541 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs753914644; called by muse, mutect2, varscan2
- ITGAM | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs757551647, COSV54940309; called by muse, mutect2, varscan2
- ITGAX | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 128/404 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV51651113; called by muse, mutect2, varscan2
- ITGB4 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1418171385; called by muse, varscan2
- ITPKA | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1406221003, COSV99540815; called by muse, mutect2, varscan2
- ITPKB | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs530318369; called by muse, mutect2, varscan2
- ITPKC | c.756dup p.Q253Tfs*4 | Frame Shift Ins (INS) | VAF 70/193 reads (36%) | catalogued as rs1484889842; called by mutect2, pindel, varscan2
- ITPRID1 | c.3106del p.S1036Lfs*13 | Frame Shift Del (DEL) | VAF 185/198 reads (93%) | catalogued as rs35589779; called by mutect2, varscan2
- ITPRIPL2 | c.901T>C p.C301R | Missense Mutation (SNP) | VAF 201/407 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67347451; called by muse, mutect2, varscan2
- ITSN1 | c.147del p.Q50Nfs*9 | Frame Shift Del (DEL) | VAF 62/186 reads (33%) | catalogued as rs746959118; called by mutect2, varscan2
- ITSN2 | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1294806839; called by muse, mutect2, varscan2
- JAK1 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61096815; called by muse, varscan2
- JAKMIP3 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs375069186; called by muse, mutect2, varscan2
- JARID2 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 236/436 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs751969709, COSV59192048; called by muse, varscan2
- JPH2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 198/380 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1188450169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JPH3 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 520/800 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52467379; called by muse, varscan2
- KALRN | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 74/210 reads (35%) | catalogued as COSV104384072; called by muse, mutect2, varscan2
- KANK1 | c.3642G>A p.M1214I | Missense Mutation (SNP) | VAF 131/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750251579, COSV66527500; called by muse, mutect2, varscan2
- KBTBD12 | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs759635530; called by muse, varscan2
- KBTBD13 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 256/567 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1293449500; called by muse, mutect2, varscan2
- KCNA7 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55503521; called by muse, mutect2, varscan2
- KCNAB3 | c.117del p.H40Tfs*39 | Frame Shift Del (DEL) | VAF 56/458 reads (12%) | catalogued as rs758175732; called by mutect2, pindel, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 150/296 reads (51%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCND1 | c.86del p.P29Rfs*5 | Frame Shift Del (DEL) | VAF 186/193 reads (96%) | catalogued as COSV99501772; called by mutect2, varscan2
- KCNH4 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as rs1220484000, COSV52917377; called by muse, mutect2, varscan2
- KCNJ10 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774033332, CM139777; called by muse, mutect2, varscan2
- KCNN1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 245/732 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1277776278; called by muse, mutect2, varscan2
- KCNQ3 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 118/347 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101195644; called by muse, mutect2, varscan2
- KCNQ3 | c.596G>A p.C199Y | Missense Mutation (SNP) | VAF 112/217 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66464704; called by muse, mutect2, varscan2
- KCNU1 | c.3058C>T p.R1020W | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV101299402, COSV67755610; called by muse, mutect2, varscan2
- KCTD13 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 180/363 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs145261639; called by muse, mutect2, varscan2
- KIAA1109 | c.4770del p.K1590Nfs*11 | Frame Shift Del (DEL) | VAF 62/117 reads (53%) | catalogued as rs779140281, COSV52689741; called by mutect2, varscan2
- KIAA1614 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 110/301 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs778528622; called by muse, mutect2, varscan2
- KIAA1614 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs763599108; called by muse, mutect2, varscan2
- KIAA1614 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 152/331 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs778547578, COSV100799828; called by muse, mutect2, varscan2
- KIAA2012 | c.2536del p.T846Qfs*16 | Frame Shift Del (DEL) | VAF 100/344 reads (29%) | catalogued as rs753894409; called by mutect2, varscan2
- KIAA2026 | c.4771C>T p.P1591S | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.426); catalogued as rs914218577, COSV67355245; called by muse, mutect2, varscan2
- KIF1A | c.4822C>T p.R1608W (on ENST00000320389 / NM_001379639.1; = p.R1600W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/548 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372429864, COSV57503238; called by muse, mutect2, varscan2
- KIF21B | c.3049G>T p.D1017Y | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59751661; called by muse, mutect2, varscan2
- KIF26A | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 164/484 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs566897705, COSV100180718; called by muse, varscan2
- KIF26B | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 243/535 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568748700, COSV100833157; called by muse, mutect2, varscan2
- KIF26B | c.3199dup p.R1067Pfs*50 | Frame Shift Ins (INS) | VAF 176/555 reads (32%) | catalogued as rs1033206065; called by mutect2, pindel, varscan2
- KIF27 | c.3936del p.S1313Vfs*5 | Frame Shift Del (DEL) | VAF 48/220 reads (22%) | catalogued as rs775622981; called by pindel, varscan2
- KIF7 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 243/486 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs900395454; called by muse, mutect2, varscan2
- KIRREL1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574166380, COSV63286398, COSV63287538; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 63/138 reads (46%) | catalogued as rs1288106608; called by mutect2, varscan2
- KMO | c.939del p.F313Lfs*5 | Frame Shift Del (DEL) | VAF 71/189 reads (38%) | catalogued as rs760795658; called by mutect2, pindel, varscan2
- KRT15 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 157/312 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1400343644; called by muse, mutect2, varscan2
- KRT39 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 167/365 reads (46%) | catalogued as rs760470392, COSV62917042; called by muse, mutect2, varscan2
- KRT83 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs775630317, COSV99531914; called by muse, varscan2
- KRTAP5-4 | c.269del p.G90Afs*148 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs757054967; called by pindel, varscan2
- LAMA1 | c.7952T>A p.I2651N | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1281852099; called by muse, mutect2, varscan2
- LAMA1 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 134/295 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.284); catalogued as rs765489991; called by muse, mutect2, varscan2
- LAMC3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 222/437 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs778884818, COSV63088242; called by muse, mutect2, varscan2
- LAMC3 | c.2321G>A p.C774Y | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754830848; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 74/169 reads (44%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | catalogued as rs746633076; called by mutect2, varscan2
- LCAT | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 151/300 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs370803551, CM950749, COSV50452455; called by muse, mutect2, varscan2
- LCLAT1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1423427344, COSV58373640; called by muse, mutect2, varscan2
- LCP1 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 145/289 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1341812865; called by muse, mutect2, varscan2
- LENG8 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 181/509 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV100457254; called by muse, mutect2, varscan2
- LEPR | c.2601G>A p.M867I | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60750358, COSV60757388; called by muse, mutect2, varscan2
- LIG3 | c.321dup p.C108Mfs*26 | Frame Shift Ins (INS) | VAF 103/221 reads (47%) | catalogued as rs779414317; called by mutect2, pindel, varscan2
- LILRA4 | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 150/566 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV99079312; called by mutect2, varscan2
- LILRB3 | c.1346G>C p.G449A (on ENST00000346401; = p.G437A on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/278 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs543988973; called by muse, mutect2, varscan2
- LIMD1 | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); catalogued as COSV99836900; called by muse, mutect2, varscan2
- LIN28B | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61493966; called by muse, mutect2, varscan2
- LINGO2 | c.1412G>T p.R471L | Missense Mutation (SNP) | VAF 198/356 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs866067533, COSV58064896; called by muse, mutect2, varscan2
- LIX1 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.855); catalogued as COSV57205962; called by muse, mutect2, varscan2
- LMOD3 | c.637dup p.I213Nfs*7 | Frame Shift Ins (INS) | VAF 154/310 reads (50%) | catalogued as rs773282804; called by mutect2, varscan2
- LPA | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs375355500; called by muse, mutect2, varscan2
- LPCAT1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 210/502 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1225430434; called by muse, mutect2
- LPP | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs770028872, COSV57089464; called by muse, varscan2
- LPXN | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs1344853080; called by muse, mutect2
- LRAT | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 155/332 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1231354939, COSV100312134, COSV60476467; called by muse, varscan2
- LRAT | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60476391; called by muse, varscan2
- LRCH4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs1245763705, COSV53823723; called by muse, mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 163/305 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRP1 | c.10765G>A p.A3589T | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs776806646; called by muse, mutect2, varscan2
- LRP1 | c.11156C>T p.T3719M | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs761861718; called by muse, mutect2, varscan2
- LRP1 | c.12547G>A p.V4183M | Missense Mutation (SNP) | VAF 177/374 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs756129605; called by muse, mutect2, varscan2
- LRP10 | c.1438C>T p.L480F | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs201600991; called by muse, mutect2, varscan2
- LRP2 | c.8131C>T p.R2711C | Missense Mutation (SNP) | VAF 191/356 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs760566317, COSV99789365; called by muse, mutect2, varscan2
- LRP3 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 250/435 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs765998277; called by muse, mutect2, varscan2
- LRRC27 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 132/287 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs533190111, COSV59808535; called by muse, varscan2
- LRRC3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.092); catalogued as rs369146695; called by muse, mutect2, varscan2
- LRRC40 | c.1076A>G p.Q359R | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.17); catalogued as COSV100918820, COSV63941580; called by muse, mutect2, varscan2
- LRRC4B | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 238/464 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV65349412; called by muse, mutect2, varscan2
- LRRC71 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs913176720; called by muse, mutect2, varscan2
- LRRC9 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 68/146 reads (47%) | catalogued as rs921668115; called by muse, varscan2
- LRRIQ3 | c.84del p.D29Ifs*5 | Frame Shift Del (DEL) | VAF 62/188 reads (33%) | catalogued as COSV63042677, COSV63048772; called by pindel, varscan2
- LRRK1 | c.3814T>C p.F1272L | Missense Mutation (SNP) | VAF 160/338 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs911429879; called by muse, mutect2, varscan2
- LRRN3 | c.1511C>A p.A504D | Missense Mutation (SNP) | VAF 85/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57823948; called by muse, mutect2, varscan2
- LRRTM1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 203/467 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54446803; called by muse, mutect2, varscan2
- LTK | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs760533366; called by muse, mutect2, varscan2
- LYST | c.9943C>T p.R3315C | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299376147, COSV101088023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LYST | c.8825A>G p.Y2942C | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs370037768; called by muse, mutect2, varscan2
- LZTR1 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 139/301 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs763222950; called by muse, mutect2, varscan2
- LZTR1 | c.2423C>T p.T808I | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs1041569569; called by muse, mutect2, varscan2
- LZTS3 | c.542dup p.Q182Afs*7 | Frame Shift Ins (INS) | VAF 147/333 reads (44%) | catalogued as rs745647523; called by mutect2, pindel, varscan2
- MACF1 | c.20188C>T p.R6730* (on ENST00000372915; = p.R4775* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 104/224 reads (46%) | catalogued as COSV57109488; called by muse, varscan2
- MAGEB6 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV66872132, COSV66872187, COSV66872197; called by muse, mutect2, varscan2
- MAGEL2 | c.1958del p.P653Rfs*49 | Frame Shift Del (DEL) | VAF 191/464 reads (41%) | catalogued as COSV100045633; called by mutect2, pindel, varscan2
- MAP2 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 27/369 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs768731263; called by muse, mutect2
- MAP3K1 | c.4299G>A p.W1433* | Nonsense Mutation (SNP) | VAF 108/209 reads (52%) | catalogued as COSV68122014; called by muse, mutect2, varscan2
- MAP3K13 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV53983534; called by muse, mutect2, varscan2
- MAP4 | c.3264T>C p.T1088= | Splice Region (SNP) | VAF 25/171 reads (15%) | catalogued as rs1307564147; called by muse, mutect2, varscan2
- MAP7D1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs935508638, COSV60217609; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 137/198 reads (69%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPK10 | c.943G>T p.A315S (on ENST00000359221 / NM_001351625.2; = p.A353S on NM_002753.5) | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100173474; called by muse, mutect2, varscan2
- MAPKBP1 | c.1233del p.S412Vfs*83 (on ENST00000456763 / NM_001128608.2; = p.S406Vfs*83 on NM_014994.3) | Frame Shift Del (DEL) | VAF 30/287 reads (10%) | catalogued as COSV52961309; called by mutect2, pindel, varscan2
- MARCHF6 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs908959812; called by muse, mutect2, varscan2
- MARCHF7 | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs193082751, COSV52027258, COSV99373416; called by muse, mutect2, varscan2
- MARF1 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770961629, COSV60027403; called by muse, mutect2, varscan2
- MARS2 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV56570805; called by muse, mutect2, varscan2
- MAT1A | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 136/256 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1202204033, CM1411205; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 88/194 reads (45%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MCC | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 227/480 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.626); catalogued as rs767529467; called by muse, mutect2, varscan2
- MCF2 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 66/66 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58477149; called by muse, varscan2
- MCM4 | c.2086A>C p.S696R | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as COSV50621098, COSV50631082; called by muse, mutect2, varscan2
- MCM7 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 237/348 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200255940; called by muse, mutect2, varscan2
- MCM7 | c.1884_1886del p.E628del | In Frame Del (DEL) | VAF 68/286 reads (24%) | catalogued as rs1269712610; called by pindel, varscan2
- MCPH1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as rs773080293; called by muse, mutect2
- MDN1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 120/231 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as rs772985231; called by muse, mutect2, varscan2
- MED12L | c.2924A>T p.D975V | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99854451; called by muse, mutect2, varscan2
- MED22 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 140/300 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); catalogued as COSV59297662; called by muse, mutect2
- MED25 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs137859678, COSV57204466; called by muse, mutect2, varscan2
- MEGF8 | c.5353C>T p.R1785W (on ENST00000251268 / NM_001271938.2; = p.R1718W on NM_001410.3) | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772299336, COSV52074564; called by muse, mutect2, varscan2
- MEP1B | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52500339; called by muse, mutect2
- METTL1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749184039; called by muse, mutect2, varscan2
- MFAP2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1247494164; called by muse, mutect2
- MFSD9 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 179/338 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762751390, COSV51493104; called by muse, mutect2, varscan2
- MGAT1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 207/422 reads (49%) | PolyPhen probably damaging (1); catalogued as rs1225858779; called by muse, mutect2, varscan2
- MIOS | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 113/371 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1260647300, COSV60768296; called by muse, mutect2, varscan2
- MITD1 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs1227813710; called by muse, mutect2, varscan2
- MMP14 | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61289802; called by muse, mutect2, varscan2
- MMP21 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 180/574 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64290372; called by muse, varscan2
- MMRN1 | c.3647del p.P1216Lfs*17 | Frame Shift Del (DEL) | VAF 55/218 reads (25%) | catalogued as COSV53334580, COSV53343010; called by mutect2, pindel, varscan2
- MOCS1 | c.1559A>G p.K520R | Missense Mutation (SNP) | VAF 138/292 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1450003502; called by muse, mutect2, varscan2
- MPIG6B | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 251/565 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.381); catalogued as COSV101008088; called by muse, mutect2, varscan2
- MPPED1 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 214/468 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs369997843; called by muse, varscan2
- MRC1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.084); catalogued as rs1471549158; called by muse, mutect2
- MROH1 | c.4117_4119del p.K1373del | In Frame Del (DEL) | VAF 163/343 reads (48%) | catalogued as rs1554834803; called by mutect2, pindel, varscan2
- MROH2B | c.2071dup p.S691Ffs*32 | Frame Shift Ins (INS) | VAF 25/157 reads (16%) | catalogued as rs1199010949; called by mutect2, pindel, varscan2
- MRPL17 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV56618218; called by muse, mutect2, varscan2
- MRPL37 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as rs768836635; called by muse, mutect2, varscan2
- MSC | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779458176, COSV57697499; called by muse, mutect2, varscan2
- MSH2 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM1314812; called by muse, mutect2, varscan2
- MSH3 | c.3382A>G p.M1128V | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1221498955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.2817A>C p.Q939H | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1553414180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSI2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 218/432 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs773391520, COSV52367034; called by muse, mutect2, varscan2
- MTA1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58757045; called by muse, mutect2, varscan2
- MTA3 | c.1681C>T p.R561W (on ENST00000405094 / NM_001330442.2; = p.R504W on NM_001282755.1) | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV101290759; called by muse, mutect2, varscan2
- MTG1 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 86/173 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as rs768253637; called by muse, mutect2, varscan2
- MTHFD1 | c.1801A>C p.S601R | Missense Mutation (SNP) | VAF 117/206 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1348501789; called by muse, mutect2, varscan2
- MTMR4 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60199364; called by muse, mutect2, varscan2
- MTMR4 | c.60dup p.K21Qfs*20 | Frame Shift Ins (INS) | VAF 104/230 reads (45%) | catalogued as rs750261859; called by mutect2, varscan2
- MTOR | c.5942A>C p.K1981T | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs567800666; called by muse, mutect2, varscan2
- MUSK | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs1484918797; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 161/400 reads (40%) | catalogued as rs764857791; called by pindel, varscan2
- MYADM | c.263G>A p.C88Y | Missense Mutation (SNP) | VAF 59/514 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.091); catalogued as rs1350077955; called by muse, mutect2, varscan2
- MYCT1 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100924103, COSV65891763; called by muse, mutect2, varscan2
- MYH10 | c.5374C>T p.R1792W | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373530537; called by muse, mutect2, varscan2
- MYH10 | c.4970A>G p.Y1657C | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV52613739; called by muse, mutect2, varscan2
- MYH10 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99344421; called by muse, mutect2, varscan2
- MYH13 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs771473458; called by muse, mutect2, varscan2
- MYH14 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 173/329 reads (53%) | catalogued as rs1452059089; called by muse, mutect2, varscan2
- MYH2 | c.3859C>T p.Q1287* | Nonsense Mutation (SNP) | VAF 71/211 reads (34%) | catalogued as COSV99820752; called by muse, mutect2, varscan2
- MYH8 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs908654941, COSV67959994; called by muse, mutect2, varscan2
- MYO15A | c.10466G>A p.R3489H | Missense Mutation (SNP) | VAF 138/278 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs747433136; called by muse, mutect2, varscan2
- MYOM3 | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs183173497; called by muse, mutect2, varscan2
- MYORG | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759830292; called by muse, mutect2, varscan2
- NAP1L1 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 112/229 reads (49%) | catalogued as rs771762505; called by muse, varscan2
- NAPSA | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143898038; called by muse, mutect2, varscan2
- NAV2 | c.3679G>A p.G1227R (on ENST00000396087 / NM_001244963.2; = p.G1204R on NM_145117.5) | Missense Mutation (SNP) | VAF 159/321 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs895534359, COSV60660428; called by muse, mutect2, varscan2
- NAV3 | c.3148A>G p.K1050E | Missense Mutation (SNP) | VAF 160/340 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745747468; called by muse, mutect2, varscan2
- NBEAL2 | c.2105G>A p.G702D | Missense Mutation (SNP) | VAF 138/332 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52754081; called by muse, mutect2, varscan2
- NBEAL2 | c.7564C>G p.R2522G | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs772546336, COSV99434001; called by muse, mutect2, varscan2
- NBPF10 | c.11138G>A p.C3713Y | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs587647639, COSV100743954; called by muse, mutect2, varscan2
- NCAPG2 | c.2990G>A p.R997Q | Missense Mutation (SNP) | VAF 169/273 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs751778174; called by muse, mutect2, varscan2
- NCOA1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs1295864492, COSV56050541; called by muse, mutect2, varscan2
- NCOR2 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 286/546 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100656723; called by muse, varscan2
- NDN | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 171/352 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs765248776, COSV59358232; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 116/273 reads (42%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NECTIN4 | c.306del p.P104Hfs*50 | Frame Shift Del (DEL) | VAF 37/416 reads (9%) | catalogued as COSV100919984; called by mutect2, varscan2*
- NEDD4 | c.1909C>T p.Q637* (on ENST00000508342 / NM_001284338.1; = p.Q218* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 30/205 reads (15%) | catalogued as COSV59065851; called by muse, mutect2, varscan2
- NEDD9 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1298082411; called by muse, mutect2, varscan2
- NEDD9 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760782051, COSV65219135; called by muse, mutect2, varscan2
3,158 further variants in this file (2,131 protein-altering or splice-affecting, 900 silent, 127 other) are not listed here.
